Somatic mutation profile of tumor specimen TCGA-QT-A5XJ-01A (aliquot TCGA-QT-A5XJ-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 42.5 years (15,535 days).
Specimen TCGA-QT-A5XJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca23fff0-1d20-4fb9-8e40-7487692e68da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XJ-10A (Blood Derived Normal), aliquot TCGA-QT-A5XJ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/819e9719-b03d-474f-9d4d-0d21f32f9e6d

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID3C | c.885C>A p.N295K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200075015; called by muse, mutect2, varscan2
- GLOD4 | c.187C>A p.P63T (on ENST00000301328 / NM_001366247.1; = p.P48T on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56755445; called by muse, mutect2, varscan2
- OLIG3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs1262073962; called by muse, mutect2, varscan2
- OR52I2 | c.581G>C p.S194T | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.214); catalogued as COSV57044348; called by muse, mutect2, varscan2
- PRG2 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 56/94 reads (60%) | catalogued as rs143145891; called by muse, mutect2
- PRKACB | c.155C>G p.T52R | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1420261664; called by muse, mutect2, varscan2
- RPS6KA5 | c.2345C>A p.P782H | Missense Mutation (SNP) | VAF 81/122 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs1197487303; called by muse, mutect2, varscan2
- TFR2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs139318596; called by muse, mutect2, varscan2
- DHTKD1 | c.2618C>G p.S873W | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- DOCK9 | c.2677G>A p.V893I (on ENST00000376460 / NM_001366676.2; = p.V894I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2
- EPC1 | c.652dup p.M218Nfs*10 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- EPOR | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- HECTD1 | c.6153A>T p.E2051D | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IVL | c.1721A>G p.Q574R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LARP4B | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2A | c.5453A>G p.Y1818C | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PTPN5 | c.344dup p.N115Kfs*23 | Frame Shift Ins (INS) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- SOX5 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF676 | c.352A>G p.T118A (on ENST00000650058; = p.T86A on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- FDXR | c.117C>T p.P39= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1240175093; called by muse, mutect2, varscan2
- KRTAP6-2 | c.18C>T p.Y6= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs375803106, COSV58182435; called by muse, mutect2, varscan2
- MATN4 | c.252C>T p.S84= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs780503822; called by muse, mutect2, varscan2
- NOP58 | c.708A>C p.A236= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- NR1H4 | c.246C>T p.F82= (on ENST00000551379 / NM_001206993.2; = p.F72= on NM_005123.4) | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs1463883415; called by muse, mutect2, varscan2
- PKN1 | c.1692G>A p.Q564= | Silent (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
